Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6539, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6539-01A (Primary Tumor).

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

F

Material: **Partial organ resection – segment of the large intestine**

Expected time of examination: **up to 8 working days**

Clinical diagnosis: **Ca. colonis.**

SPECIMEN – transverse colon with tumour.

Examination performed on:

Macroscopic description:

A 25.3 cm length of the large intestine with a segment of the mesentery sized 25 x 6 x 2 cm. Ulcerous tumour sized 3 x 2 cm found in the mucosa. The lesion surrounds 100% of the intestine circumference, narrowing its lumen, removed 4.5 cm away on e of the incision lines and 4.5 cm from the opposite one. The lesion infiltrates macroscopically the wall of the large intestine and the periintestinal tissue. Minimal side margin is 1 cm. Mucosa unchanged outside the tumour.

Microscopic description:

Adenocarcinoma tubulare (GI). Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae. Minimal side margin is 1 cm. Incision lines free of neoplastic lesions. Lymphonodulitis reactiva lymphonodorum (No XII).

Histopathologic diagnosis:

Adenocarcinoma tubulare coli (GI, Dukes B, Astler-Coller B2, pT3, pNO).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 52f69ae7-c89d-47e8-84c8-7ca4cae4f0c5 (TCGA-D5-6539.3AFFDCB5-2A67-43C9-93AA-1191B1A1197E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).